Somatic mutation profile of tumor specimen 0DHMR5 from CCDI case PBBUHJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,515 days).
Specimen 0DHMR5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03862045-d6de-44de-b317-ca1d76930781.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHMLT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/037e1f80-05e2-4812-b86e-807e34631086

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 6, Splice Site 2, Intron 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10D | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 266/530 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs909732631; called by muse, mutect2, varscan2
- CBFA2T2 | c.361C>G p.R121G | Missense Mutation (SNP) | VAF 722/754 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60074079; called by muse, mutect2, varscan2
- FLNC | c.1874C>A p.S625Y | Missense Mutation (SNP) | VAF 114/1036 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1245272087; called by muse, mutect2, varscan2
- SMARCA4 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 339/855 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60786176; called by muse, mutect2, varscan2
- ARID1A | c.3866+2T>G p.X1289_splice | Splice Site (SNP) | VAF 34/763 reads (4%) | called by muse, mutect2
- ERC2 | c.1921-1G>C p.X641_splice | Splice Site (SNP) | VAF 286/656 reads (44%) | called by muse, mutect2, varscan2
- NXF1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 226/534 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- UROC1 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 267/583 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- YIPF4 | c.384dup p.S129Ifs*7 | Frame Shift Ins (INS) | VAF 142/311 reads (46%) | called by mutect2, varscan2
- ABHD18 | c.108A>G p.R36= | Silent (SNP) | VAF 118/320 reads (37%) | called by muse, mutect2, varscan2
- FAM221B | c.1185C>T p.V395= | Silent (SNP) | VAF 195/450 reads (43%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1494G>A p.P498= | Silent (SNP) | VAF 346/783 reads (44%) | catalogued as rs1397587954; called by muse, mutect2, varscan2
- NOS3 | c.831C>T p.H277= | Silent (SNP) | VAF 68/1038 reads (7%) | catalogued as rs371246886; called by muse, mutect2
- PRAMEF15 | c.99G>T p.L33= | Silent (SNP) | VAF 42/1216 reads (3%) | called by muse, mutect2
- PRAMEF9 | c.99G>T p.L33= | Silent (SNP) | VAF 19/271 reads (7%) | called by muse, mutect2
- IQCJ-SCHIP1 | c.1224+44C>T | Intron (SNP) | VAF 109/226 reads (48%) | catalogued as rs756515978; called by muse, mutect2, varscan2
- KRT79 | c.1402+88C>T | Intron (SNP) | VAF 98/197 reads (50%) | catalogued as rs1565688977; called by muse, mutect2, varscan2
- PRTG | c.*72T>G | 3'UTR (SNP) | VAF 95/177 reads (54%) | called by muse, mutect2, varscan2
